Somatic mutation profile of tumor specimen C3L-00137-02 (aliquot CPT0002010008) from CPTAC case C3L-00137, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.6 years (22,142 days).
Specimen C3L-00137-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ac5c3c5-155e-4759-a45a-e9ed5daf1897.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00137-31 (Blood Derived Normal), aliquot CPT0003870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a9a60b7-d7c5-4975-b55c-5cccc194a69a

The open-access MAF lists 59 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Intron 5, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 2, 5'Flank 2, 3'UTR 1, Nonsense Mutation 1, Nonstop Mutation 1, IGR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 176/463 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 195/451 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 78/245 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- CTCF | c.2183G>T p.*728Lext*48 | Nonstop Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV50465069; called by muse, mutect2, varscan2
- GPR50 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs770934441, COSV54439488; called by muse, mutect2, varscan2
- KIAA1549L | c.4780G>A p.A1594T (on ENST00000321505; = p.A1891T on NM_012194.3) | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs776673634; called by muse, mutect2, varscan2
- KRI1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs778985203, COSV57265801; called by muse, mutect2, varscan2
- MAN1B1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 161/418 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100857455; called by muse, mutect2, varscan2
- NUP155 | c.1933C>G p.Q645E (on ENST00000231498 / NM_153485.3; = p.Q586E on NM_004298.4) | Missense Mutation (SNP) | VAF 135/298 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99195395; called by muse, mutect2, varscan2
- PCDHGA2 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 175/500 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53901834; called by muse, mutect2, varscan2
- PCSK9 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 118/324 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as CM1514945; called by muse, varscan2
- PFKP | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs148701004; called by muse, mutect2, varscan2
- POLG | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1064796726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121L12 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); catalogued as COSV68692958, COSV68693988; called by muse, mutect2, varscan2
- PTEN | c.540C>A p.Y180* | Nonsense Mutation (SNP) | VAF 75/224 reads (33%) | catalogued as CM074469, HM971505, COSV64292582; called by muse, mutect2, varscan2
- TBC1D4 | c.2768G>A p.R923Q | Missense Mutation (SNP) | VAF 127/356 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs762794443; called by muse, mutect2, varscan2
- UTP25 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.915); catalogued as rs761990820; called by muse, mutect2, varscan2
- VIP | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.851); catalogued as COSV100923930; called by muse, mutect2, varscan2
- AGTR1 | c.709_711del p.D237del | In Frame Del (DEL) | VAF 88/206 reads (43%) | called by pindel, varscan2
- ARID1A | c.1620_1633del p.T541Pfs*77 | Frame Shift Del (DEL) | VAF 118/334 reads (35%) | called by mutect2, pindel, varscan2
- CAMK1G | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CEACAM20 | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 128/399 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- CEP250 | c.539T>A p.L180Q | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CLEC4G | c.215C>A p.T72K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CTCF | c.1718A>C p.H573P | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CYFIP1 | c.3493_3495del p.I1165del | In Frame Del (DEL) | VAF 78/208 reads (38%) | called by pindel, varscan2
- FAT2 | c.9500G>T p.G3167V | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDNF | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.301); called by muse, mutect2
- GLUD2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 79/747 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HACE1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 99/152 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IGSF1 | c.3878G>C p.G1293A | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- INA | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.561); called by muse, mutect2
- MTRNR2L8 | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- PGR | c.1624dup p.L542Pfs*32 | Frame Shift Ins (INS) | VAF 77/232 reads (33%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1735_1745del p.Q579Vfs*19 (on ENST00000521381 / NM_181523.3; = p.Q309Vfs*19 on NM_181504.4) | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | called by pindel, varscan2
- PLPPR4 | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTEN | c.353dup p.H118Qfs*8 | Frame Shift Ins (INS) | VAF 176/530 reads (33%) | called by mutect2, pindel, varscan2
- SOS2 | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- STARD9 | c.11024C>G p.T3675S | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- UBP1 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- UBTD2 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADARB1 | c.1749G>A p.S583= (on ENST00000360697 / NM_001346687.2; = p.S543= on NM_001112.4) | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as rs372954828; called by muse, mutect2, varscan2
- KLHDC7A | c.1800C>T p.N600= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- MROH5 | c.822G>A p.T274= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs370198363; called by muse, mutect2, varscan2
- PCNX3 | c.438C>G p.V146= | Silent (SNP) | VAF 114/231 reads (49%) | called by muse, mutect2, varscan2
- PRSS36 | c.1692C>T p.A564= | Silent (SNP) | VAF 87/245 reads (36%) | called by muse, mutect2, varscan2
- RIPOR2 | c.129C>T p.S43= | Silent (SNP) | VAF 53/121 reads (44%) | catalogued as rs370164838, COSV52427716; called by muse, mutect2, varscan2
- VSX1 | c.318G>T p.V106= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- ZNF627 | c.759C>T p.C253= | Silent (SNP) | VAF 73/207 reads (35%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9340G>A | Intron (SNP) | VAF 199/501 reads (40%) | catalogued as COSV101595501; called by muse, mutect2, varscan2
- ADCYAP1 | chr18:904833 G>A | 5'Flank (SNP) | VAF 33/151 reads (22%) | catalogued as rs1376354735; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500073 del GA | 5'Flank (DEL) | VAF 80/229 reads (35%) | called by pindel, varscan2
- ERI2 | c.643+41A>C | Intron (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- MC3R | c.-30C>T | 5'UTR (SNP) | VAF 82/241 reads (34%) | called by muse, mutect2, varscan2
- OFCC1 | n.1717+18591T>C | Intron (SNP) | VAF 50/150 reads (33%) | catalogued as rs115531980; called by muse, mutect2, varscan2
- PIK3C2B | c.*127A>G | 3'UTR (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13281C>A | Intron (SNP) | VAF 46/122 reads (38%) | called by muse, mutect2, varscan2
- SYNGR3 | c.338-17C>T | Intron (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- Unknown | chr17:43379165 C>T | IGR (SNP) | VAF 67/184 reads (36%) | called by muse, mutect2, varscan2
